HCMI case HCM-CSHL-1263-C24 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f394d2fb-970d-4d9f-82b1-3f16abfe2d55

Demographics
Sex at birth: male; Year of birth: 1944; Vital status: Dead; Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C24.1; Tissue or organ of origin: Ampulla of Vater; Classification of tumor: primary; Age at diagnosis: 76.7 years (28,014 days); AJCC staging edition: 8th; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: No; Residual disease: R0; Sites of involvement: Liver.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: Yes; Perineural invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -12 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Ampulla of Vater; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 76.7 years (28,014 days); Residual disease: R0.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: Yes; Perineural invasion present: No.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Follow-up contacts recording only the day: day 219, day 338.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 90 kg; Height: 175 cm; BMI: 29.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-CSHL-1263-C24-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-1263-C24-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
